Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EQ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EQ-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:

[REDACTED] with synovial sarcoma of the right popliteal region.

Specimens Submitted:

1: SP: Radical resection distal right thigh and popliteal resection

DIAGNOSIS:

- 1) THIGH, RIGHT DISTAL AND POPLITEAL; RESECTION:
- MONOPHASIC SYNOVIAL SARCOMA.
- TUMOR MEASURES 4.2 CM GREATEST DIMENSION, INVOLVES FIBROADIPOSE TISSUE, AND ENCASES A 0.5 CM DIAMETER ARTERY.
- MITOTIC RATE IS 15/10 HPF; TUMOR SHOWS ABOUT 5% NECROSIS.
- VASCULAR INVASION IS PRESENT.
- MARGINS ARE WIDELY FREE OF TUMOR.
- CHANGES CONSISTENT WITH PRIOR BIOPSY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1). The specimen is received fresh, labeled "Radical resection distal right thigh and popliteal resection" and consists of a piece of soft tissue with attached skin ellipse, measuring 15.6 x 7.8 x 6.5 cm. A short stitch indicates the superior margin, and a long stitch indicates the lateral margin. The specimen is inked: superiorred, inferioryellow, posteriorblack, medialgreen, lateralblue. The skin measures 14.2 x 4.5 cm. Sections show a circumscribed tan nodular calcified mass measuring 4.2 x 3.5 x 3.0 cm. which is located 2.0 cm from superior margin, 1.0 cm from

** Continued on next page **

ICD O-3
Sarcoma, synovial monophasic
fibrous 9041/3
Site (R) Popliteal space, right tissue
Q49.2
QW 9/26/13

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
posterior margin, 0.8 cm from inferior margin, 1.3 cm from lateral margin
and far away from skin and medial margins. Tumor wraps around a medium-sized
blood vessel. Representative sections are submitted. TPS and photograph are
taken. Calcified tissue is submitted for decalcification.

Summary of sections:

S - superior margin
I - inferior margin
M - medial margin
L - lateral margin
A - anterior margin (skin)
P - posterior margin
T-tumor
VM-vessel margins
TIP-skin tips

Summary of Sections:

Part 1: SP: Radical resection distal right thigh and popliteal resection

Block	Sect.	Site	PCs	
1		{not entered}		1
1		a	1	
1		i	1	
1		l	1	
1		m	1	
1		p	1	
1		s	1	
5		t	5	
2		tip	2	
1		vm	1	

** End of Report **

Criteria	hw 8/26/13	Yes	No
IHPAA Discrepancy			✓

[page 3 of 4]
SURGICAL PATHOLOGY CONSULT

Patient: [REDACTED]

Specimens Submitted:

1: SOFT TISSUE - BX. RT. POPLITEAL MASS, [REDACTED] (23 SLIDES, 1 BLOCK)

DIAGNOSIS:

Consistent with synovial sarcoma

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

Dear

Thank you for asking my opinion in this interesting and challenging case. I agree entirely with your interpretation, that based on the morphologic appearance and the submitted immunohistochemical stains, this popliteal mass is most consistent with a monophasic synovial sarcoma. The lesion is composed of a highly cellular proliferation of monomorphic spindle cells separated by a delicate collagenous stroma. The reactivity for EMA and focally for AE1:AE3 further support this diagnosis.

In spite of the classic morphologic and immunophenotypic appearance of the lesion, the clinical presentation (patient's age) is somewhat unusual for this diagnosis. Thus, I have submitted the paraffin block for molecular analysis for the presence of the SYT-SSX fusion transcript, specific of synovial sarcoma, and the results will be issued in a separate report.

Sincerely,

Associate Attending pathologist

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY CONSULT

Patient: [REDACTED]

[REDACTED]

[REDACTED]

----- Page 2 of 2

Summary of Sections:

Part 1: SOFT TISSUE - BX. RT. POPLITEAL MASS, [REDACTED] (23 SLIDES, 1 BLOCK)

** End of Report **

Source: NCI Genomic Data Commons file 6f2632c1-1ffc-4e92-891c-28f6a92d299c (TCGA-DX-A7EQ.ABB1D3C7-EDF3-4F04-93A1-88E41846747B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).